CGCI case BLGSP-71-30-00647 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e2346f57-311a-4d9c-a7c9-891223e5ce2a

Demographics
Sex at birth: male; Age at index: 67 years; Vital status: Dead; Days to death: 1,224 days (3.4 years); Cause of death: Cancer Related.

Diagnoses (2)
1. Burkitt lymphoma, NOS (Includes all variants) (the primary disease): ICD-O-3 morphology code: 9687/3; Tissue or organ of origin: Hematopoietic system, NOS; Site of resection or biopsy: Connective, subcutaneous and other soft tissues of head, face, and neck; Classification of tumor: primary; Age at diagnosis: 67.1 years (24,516 days); Year of diagnosis: 2007; Method of diagnosis: Excisional Biopsy; Ann Arbor pathologic stage: Stage II; Ann Arbor B symptoms: No; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 1,220 days (3.3 years); Ann Arbor extranodal involvement: Yes; Burkitt lymphoma clinical variant: Sporadic, adult; Max tumor bulk site: Neck; Sites of involvement: Soft tissue.
   Pathology details: Bone marrow malignant cells: No; Lymph node involved site: Cervical, NOS; Lymph nodes positive: 1; Lymph nodes tested: 11; Tumor largest dimension diameter: 6 cm.
   Treatment given: Treatment type: Chemotherapy; Initial disease status: Initial Diagnosis; Days to treatment start: 42 days; Days to treatment end: 45 days; Number of cycles: 1; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 100 days; Days to treatment end: 113 days; Treatment dose: 30; Treatment outcome: Complete Response; Treatment anatomic sites: Head, Face or Neck, NOS.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis.
2. Tumor, NOS: Tissue or organ of origin: Lung, NOS; Classification of tumor: Synchronous primary; Age at diagnosis: 70.5 years (25,733 days); Days to diagnosis: 1,217 days (3.3 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, for initial diagnosis; Radiation Therapy, NOS, for initial diagnosis; Surgery, NOS, for initial diagnosis.

Follow-up (2 entries)
- Days to follow up: 0 days; ECOG performance status: 2.
- Days to follow up: 1,220 days (3.3 years); Disease response: Tumor Free.

Molecular and laboratory tests
- BCL2 (IHC): Negative.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- CD10 (IHC): Negative; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- MIB1 (IHC): Negative.
- MYC translocation (FISH): Abnormal, NOS.
- Test (IHC): Negative; Specialized molecular test: TdT.
- Lactate Dehydrogenase 545 [Blood test normal range upper: 618].

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample BLGSP-71-30-00647-01A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Other; Preservation method: FFPE; Days to sample procurement: 0 days; Method of sample procurement: Excisional Biopsy; Tissue collection type: Retrospective.
- Sample BLGSP-71-30-00647-01Z: Sample type: Tumor; Tissue type: Tumor.
  Slide BLGSP-71-30-00647-01-Ki67: Tissue microarray coordinates: A3,B3.
  Slide BLGSP-71-30-00647-01-BCL6: Tissue microarray coordinates: A3,B3.
  Slide BLGSP-71-30-00647-01-CD20: Tissue microarray coordinates: A3,B3.
  Slide BLGSP-71-30-00647-01-CD10: Tissue microarray coordinates: A3,B3.
  Slide BLGSP-71-30-00647-01-CD3: Tissue microarray coordinates: A3,B3.
  Slide BLGSP-71-30-00647-01-EBER: Tissue microarray coordinates: A3,B3.
  Slide BLGSP-71-30-00647-01-BCL2: Tissue microarray coordinates: A3,B3.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Lost to follow-up: No; New tumor event diagnosis indicator: Yes.
- Primary pathology: Histologic diagnosis: Burkitt lymphoma (BL), classic morphology; Extranodal site involvement: 1; Extranodal involvment other: Soft Tissue; Lymph nodes examined: Yes.
- Primary pathology, Lymph node involvement sites: Lymph node involvement site: cervical.
- Primary pathology, Pos lymph node locations: Pos lymph node location: Supraclavicular.
- Stage record, Ann arbor: B symptoms present indicator: No.
- Tests performed: LDH level: 545; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 1: Immunophenotypic analysis tested: CD20.
- Tests performed, Genetic testing results, Genetic testing result 3: Immunophenotypic analysis tested: BCL2.
- Tests performed, Genetic testing results, Genetic testing result 5: Immunophenotypic analysis tested: Tdt.
- Tests performed, Genetic testing results, Genetic testing result 6: Immunophenotypic analysis tested: MIB-1.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 1: Genetic abnormality tested: C-myc.
- New tumor event: New tumor event type: New Primary Tumor; New tumor event site other: Lung primary with brain and bony metases; New tumor event diagnosis evidence: Biopsy with Histologic Confirmation; New tumor event surgery: No; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No.
- Treatments, Treatment 1: Therapy regimen: Initial; Chemo end reporting period: Yes; Pharmaceutical regimen: CODOX + Rituximab; Pharma adjuvant cycles count: 1.
- Treatments, Treatment 2: Therapy regimen: Initial; Treatment type: Radiation Therapy; Radiation therapy end: Yes; Radiation therapy total dosage: 30.
- Treatments, Treatment 2, Extranodal radiation field list: Extranodal radiation field: Head, Face, or Neck.
- Treatments, Treatment 2, Targeted nodal region list: Targeted nodal region: Cervical; Targeted nodal region: Supraclavicular.

Additional fields from the CGCI biospecimen supplement workbook CGCI-BLGSP_biospecimenSupplementSpreadsheet_TWIST_20220304.xlsx (sheet Sheet1), for sample BLGSP-71-30-00647-01A-01E-0001-01:
- % tumour: 80
